TCGA case TCGA-36-2539 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: BC Cancer Agency.
https://portal.gdc.cancer.gov/cases/81d11171-5d9e-4950-98f8-b0ab0f2d7908

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-36-2539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-36-2539-01A-01-TS1: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 85; Percent normal cells: 8; Percent necrosis: 3; Percent stromal cells: 10.
  Slide TCGA-36-2539-01A-01-BS1: Section location: Bottom; Percent tumor cells: 57; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 40.
- Sample TCGA-36-2539-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-36-2539-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy of L breast cancer. No systemic chemotherapy or radiation. Prior malignancy R breast cancer treated with taxoterene.
- Prior malignancy: Prior malignancy of breast ductal and lobular carcinoma.
- Prior malignancy: Prior malignancy of L breast cancer. No systemic chemotherapy or radiation. Prior malignancy R breast cancer treated with taxoterene.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-36-2539-01): tumor purity 0.58, ploidy 1.8, whole-genome doublings 0 (call status: legacy_call).
